Somatic mutation profile of tumor specimen TARGET-40-0A4I6O-01A (aliquot TARGET-40-0A4I6O-01A-01Y) from TARGET case TARGET-40-0A4I6O, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.4 years (6,738 days).
Specimen TARGET-40-0A4I6O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7ee2d9d-5361-4087-a823-473647a2d3e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I6O-10A (Blood Derived Normal), aliquot TARGET-40-0A4I6O-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d75790e-2440-414e-a668-1e0404ffc272

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Silent 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYBPC1 | c.1447G>A p.G483R (on ENST00000550270 / NM_206820.2; = p.G508R on NM_002465.4) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs772728435, COSV62251590; called by muse, mutect2, varscan2
- MYBPC1 | c.1448G>A p.G483E (on ENST00000550270 / NM_206820.2; = p.G508E on NM_002465.4) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV62252714; called by muse, mutect2, varscan2
- SYNC | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.251); catalogued as COSV65130771; called by muse, varscan2
- CACNG2 | c.255_263del p.E85_A87del | In Frame Del (DEL) | VAF 20/31 reads (65%) | called by mutect2, pindel, varscan2
- THOC6 | c.515A>T p.H172L | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- KHNYN | c.2022C>T p.L674= | Silent (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- PPIC | c.*34A>G | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
